Somatic mutation profile of tumor specimen TCGA-DX-A6BE-01A (aliquot TCGA-DX-A6BE-01A-41D-A32I-09) from TCGA case TCGA-DX-A6BE, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 77.7 years (28,368 days).
Specimen TCGA-DX-A6BE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f4501b2-3501-447b-9b58-0b8253b83d7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6BE-10A (Blood Derived Normal), aliquot TCGA-DX-A6BE-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0471e70c-a85d-4ed9-b73e-2adbddcf14dd

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT1 | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 33/632 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV100356540; called by muse, mutect2
- BBS9 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.03); catalogued as COSV99629750; called by muse, mutect2, varscan2
- CCDC125 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101143723; called by mutect2, varscan2
- COL11A2 | c.1976T>G p.L659R (on ENST00000341947 / NM_080680.3; = p.L552R on NM_080679.2) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100554456; called by muse, mutect2, varscan2
- FLG2 | c.5458C>T p.H1820Y | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as COSV66169500; called by muse, mutect2, varscan2
- HDAC9 | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV101287226, COSV67781572; called by muse, mutect2
- MARCHF2 | c.452T>A p.L151Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99294880; called by muse, mutect2, varscan2
- NDUFA7 | c.44C>A p.A15E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV100035636; called by muse, mutect2, varscan2
- NKAIN3 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs758156404, COSV60665879; called by muse, mutect2, varscan2
- NYAP2 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1401225250, COSV99798242; called by muse, mutect2
- OLFM2 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 75/476 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV99322004; called by muse, mutect2, varscan2
- PGA5 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.211); catalogued as COSV100409386; called by muse, mutect2, varscan2
- PTPRO | c.2461G>T p.V821L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99841557; called by muse, mutect2, varscan2
- RIMS1 | c.4178G>T p.R1393I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99326259; called by muse, mutect2, varscan2
- SCN4A | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.286); catalogued as COSV101438634; called by muse, mutect2, varscan2
- SLC16A13 | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100338738; called by muse, mutect2, varscan2
- SYT1 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV99697193; called by muse, mutect2
- TRHDE | c.2395T>C p.F799L | Missense Mutation (SNP) | VAF 57/372 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99672229; called by muse, mutect2, varscan2
- YOD1 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60005983; called by muse, mutect2, varscan2
- CSMD1 | c.9885C>T p.F3295= (on ENST00000520002; = p.F3294= on NM_033225.6) | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs781556274, COSV59286211; called by muse, mutect2, varscan2
- FCRL3 | c.885C>T p.T295= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs754929262, COSV63840429, COSV63843858; called by muse, mutect2, varscan2
- HEATR5A | c.2886T>G p.S962= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV101120464; called by muse, mutect2, varscan2
- HOXB6 | c.240C>T p.F80= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99494714; called by mutect2, varscan2
